Surgical pathology report (de-identified scan), TCGA case TCGA-A2-A1G1, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Walter Reed, specimen TCGA-A2-A1G1-01A (Primary Tumor).

[page 1 of 2]
Carcinoma, infiltrating ductal, NOS 8500/3

Site: breast, NOS C50.9 1/25/11

SURGICAL REPORT

Name:

Sex: F

DOB

Location:

Doctor:

Pathology Number:

Date Collected: (

Date Received:

M.R. Number

Account Number

PRE-OPERATIVE DIAGNOSIS

RIGHT BREAST CA

POST-OPERATIVE DIAGNOSIS

RIGHT BREAST CA

PROCEDURE

RIGHT BREAST LUMPECTOMY WITH SENTINEL LYMPH NODE BIOPSY, F.S.; POSSIBLE AXILLARY DISSECTION

TISSUES

- A. BREAST EXCISION, NEEDLE LOC, SIMPLE, MARGINS, ETC. - RIGHT BREAST LUMP
B. SENTINEL LYMPH NODE (S) - #1 "FS"

FS DIAGNOSIS

- A. RIGHT BREAST LUMP (GROSS MARGINS) -
MARGINS GROSSLY NEGATIVE FOR MALIGNANCY.
B. RIGHT SENTINEL LYMPH NODE #1, F.S. -
SENTINEL NODE #1, NEGATIVE FOR MALIGNANCY.

(REPORTED TO SURGEON:

Diagnosed by:

FINAL DIAGNOSIS

- A. RIGHT BREAST LUMP -
POORLY DIFFERENTIATED INFILTRATING DUCTAL CARCINOMA WITH CENTRAL
NECROSIS (SCARFF-BLOOM-RICHARDSON GRADE II/III).
THE TUMOR MEASURES 3 CM. IN MAXIMUM DIMENSION.
LYMPHOVASCULAR INVASION IDENTIFIED INSIDE THE TUMOR.
ALL SURGICAL MARGINS ARE FREE OF THE TUMOR.
B. RIGHT SENTINEL LYMPH NODE #1 -
ONE POSITIVE LYMPH NODE (1/1).

PTNM CLASSIFICATION: STAGE IIB, T2 N1 MX.

PQR CATEGORY II: 3260F

Diagnosed by:

Reviewed and electronically signed out by:

Patient Name

SURGICAL REPORT

Pathology Number:

[page 2 of 2]
Patient Name

Pathology Number: 130

COMMENT

Specimen "B" shows metastatic carcinoma which is shown in the permanent section and not in the frozen section.

This case is discussed with Dr.

GROSS DESCRIPTION

The specimen is received in two separate containers labeled _____ designated A and B.

- A. The container is received fresh unfixed labeled "right breast lump" and consists of a 33 gm. ovoid mass of apparent fatty and fibrous-encased tissue which is 5.5 x 4.5 x 2 cm. in greatest overall dimension. There are two sutures indicating superior margin inked with yellow dye, inferior is inked green. There is a single short suture indicating lateral margin inked with orange dye, medial is inked black. There is a single short suture indicating anterior margin inked with blue dye, posterior is inked red. Sectioning reveals a tumor which is 3 x 2.5 x 1 cm. in greatest overall dimension and grossly appears to be 0.4 cm. from the superior/yellow, 0.9 cm. from the inferior/green, 0.4 cm. from the medial/black, 0.3 cm. from the lateral/orange, 0.5 cm. from the anterior/blue, 0.6 cm. from the posterior/red. The specimen is submitted in twelve blocks.

Key Note Block Summary: 1—superior, 2—inferior, 3—medial, 4—lateral, 5—anterior, 6—posterior, 7 through 9—tumor, 10 through 12—random.

- B. The container is received fresh unfixed labeled "right sentinel lymph node #1 for frozen section" and consists of an ovoid mass of apparent fat which is 1.5 x 1 x 0.6 cm. in greatest overall dimension. Sectioning reveals a 1 cm. pink-tan firm nodule. Touch prep and frozen section are obtained by Dr. _____ The entire specimen including frozen section is submitted in two blocks.

MICROSCOPIC EXAM

MICROSCOPIC EXAMINATION CONDUCTED BY PATHOLOGIST CONFIRMS FINAL DIAGNOSIS.

Patient Name

Pathology Number:

SURGICAL REPORT

Page 2 of 2

Source: NCI Genomic Data Commons file 6fa0b644-b009-401d-ae8d-09f4a0b8f876 (TCGA-A2-A1G1.E2E6CA22-AFE4-4B8F-90AC-32639687A590.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).